Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7247, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7247-01A (Primary Tumor).

Received [REDACTED]

Pathologist

Accession: [REDACTED]

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****

**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) LEFT SUPERIOR LARYNGEAL NERVE:
Peripheral nerve, no tumor present.
- (B) PHARYNGEAL MARGIN, SUPERIOR:
Squamous mucosa and skeletal muscle, no tumor present.
- (C) ESOPHAGEAL MARGIN:
Portion of esophagus, no tumor present.
- (D) TOTAL LARYNGOPHARYNGECTOMY:
INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA,
MULTIFOCAL, PREDOMINANTLY INVOLVING THE LEFT PYRIFORM SINUS
MUCOSA. (SEE COMMENT)
DEPTH OF INVASION 0.5 CM.
EXTENSIVE LYMPHATIC INVASION.
Tracheal margin, no tumor present.
Three left subdigastric lymph nodes, no tumor present.
Three left lower jugular lymph nodes, no tumor present.
Three right mid jugular lymph nodes, no tumor present.
Thyroid, no tumor present.
Parathyroid, no tumor present.
Skin, no tumor present.

COMMENT

The main tumor arises in the pyriform sinus and measures 3.2 x 1.5 x 0.5 cm. Three distinctly separate areas of invasive squamous carcinoma are present in the left subglottic mucosa along with two submucosal deposits in the anterior commissure and right true vocal cord.

[REDACTED]

SPECIMEN

- (A) LEFT SUPERIOR LARYNGEAL NERVE:
- (B) PHARYNGEAL MARGIN, SUPERIOR:
- (C) ESOPHAGEAL MARGIN:
- (D) TOTAL LARYNGOPHARYNGECTOMY:

SNOMED CODES

T-55000,M-80703

Source: NCI Genomic Data Commons file ac7ceca9-5be8-4bb6-bca4-00db0e2776e0 (TCGA-CV-7247.5ACFA8BB-C3D2-4BDE-A04A-620B7C15916A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).